Gene-level copy-number profile of tumor specimen RC-B65M-TBP1-A from RC case RC-B65M, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adult T-cell leukemia/lymphoma (HTLV-1 positive) (includes all variants); Tissue or organ of origin: Lymph node, NOS; Age at diagnosis: 40.4 years (14,739 days).
Specimen RC-B65M-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 80c281fd-7fb2-4327-9d6d-4b422c4d17ab.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator RC-B65M-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/54582add-3bd6-408f-afa1-fd55539280ed

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 132; copy number 1: 1,023; copy number 2: 49,661; copy number 3: 7,563; copy number 4: 10.

Homozygous deletions (total copy number 0; autosomes only): 131 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:21,749,178–22,552,156, 124 genes (within-gene range 0–2) (broad region; genes not listed).
- chr17:45,506,741–45,563,230, 7 genes: LRRC37A4P, Metazoa_SRP, AC091132.3, AC091132.1, AC091132.4, AC091132.5, RDM1P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,019. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
